Somatic mutation profile of cancer-model specimen HCM-CSHL-0317-C18-85A (3D Organoid; aliquot HCM-CSHL-0317-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-CSHL-0317-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-CSHL-0317-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a35485c-b6ba-4d36-8d34-140f8c0b9fe2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0317-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0317-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93459cd4-2b9f-4c57-aeff-f37e354f48b9

The open-access MAF lists 1,639 somatic variants for this specimen: 1,214 protein-altering or splice-affecting, 350 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 896, Silent 350, Frame Shift Del 166, Frame Shift Ins 84, Intron 48, Nonsense Mutation 32, Splice Site 14, 3'UTR 14, Splice Region 12, In Frame Del 8, 5'Flank 6, 5'UTR 4.

Variants (750 of 1,639; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADSL | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 120/275 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs796052248, COSV53411299; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDCA7 | c.820C>T p.R274C (on ENST00000347703 / NM_145810.3; = p.R353C on NM_031942.5) | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs879253738, CM157791, COSV60720568; ClinVar: pathogenic; called by muse, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 84/151 reads (56%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 146/256 reads (57%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 343/343 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 139/276 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PSEN2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 180/351 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs63750048, CM081407; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- SCNN1B | c.1789del p.R597Afs*79 | Frame Shift Del (DEL) | VAF 264/565 reads (47%) | catalogued as rs758629218, COSV56301349; ClinVar: pathogenic; called by mutect2, varscan2
- SOS1 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs397517159, CM070272, COSV67673763; ClinVar: pathogenic; called by muse, varscan2
- ABCA3 | c.4214C>T p.A1405V | Missense Mutation (SNP) | VAF 174/365 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs149559041; called by muse, mutect2, varscan2
- ABCC9 | c.2599G>A p.V867I | Missense Mutation (SNP) | VAF 104/259 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.353); catalogued as rs376754153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD3 | c.97C>A p.L33I | Missense Mutation (SNP) | VAF 166/351 reads (47%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.899); catalogued as COSV100238872; called by muse, varscan2
- ABCD4 | c.605A>G p.K202R | Missense Mutation (SNP) | VAF 168/361 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.152); catalogued as rs759130291; called by muse, mutect2, varscan2
- ABLIM2 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777683715; called by muse, mutect2, varscan2
- ABRAXAS2 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 127/273 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.877); catalogued as COSV53717177; called by muse, mutect2, varscan2
- ACACB | c.3253G>A p.A1085T | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV100622875; called by muse, mutect2, varscan2
- ACKR4 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 153/476 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1398393923, COSV51442163; called by muse, mutect2, varscan2
- ACTL9 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 210/441 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1555753278, COSV61005059; called by muse, varscan2
- ACTL9 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 186/408 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs782721280, COSV61006019; called by muse, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 105/222 reads (47%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS12 | c.2845A>G p.T949A | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.086); catalogued as rs933531471; called by muse, mutect2, varscan2
- ADAMTS17 | c.3121dup p.R1041Pfs*98 | Frame Shift Ins (INS) | VAF 151/409 reads (37%) | catalogued as rs771906146; called by mutect2, pindel, varscan2
- ADAMTSL2 | c.1789G>A p.V597I | Missense Mutation (SNP) | VAF 190/383 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs1460344385; called by muse, mutect2, varscan2
- ADCY1 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 90/285 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749480692, COSV52031461; called by muse, varscan2
- ADGB | c.266T>C p.I89T | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1165603824; called by muse, mutect2, varscan2
- ADGRG5 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 176/373 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs536655478, COSV61083664; called by muse, mutect2, varscan2
- ADSS1 | c.197del p.X66_splice | Splice Site (DEL) | VAF 104/262 reads (40%) | catalogued as rs760706338; called by mutect2, pindel, varscan2
- AFAP1 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 147/285 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.132); catalogued as COSV61793303; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 137/284 reads (48%) | catalogued as COSV62339755; called by mutect2, varscan2
- AL592490.1 | c.2456G>A p.R819H | Missense Mutation (SNP) | VAF 153/271 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs1047769718, COSV101308259; called by muse, mutect2, varscan2
- ALDH16A1 | c.1039del p.A347Lfs*155 | Frame Shift Del (DEL) | VAF 237/570 reads (42%) | catalogued as rs1368010977; called by mutect2, pindel, varscan2
- ALG8 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 98/213 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1159069584; called by muse, mutect2, varscan2
- ALK | c.2327G>T p.G776V | Missense Mutation (SNP) | VAF 135/275 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101202107, COSV101202921; called by muse, mutect2, varscan2
- ALPK2 | c.2575A>G p.T859A | Missense Mutation (SNP) | VAF 174/305 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs1296247247; called by muse, mutect2, varscan2
- ANGPTL2 | c.1456C>T p.R486* | Nonsense Mutation (SNP) | VAF 143/284 reads (50%) | catalogued as COSV52221443; called by muse, mutect2, varscan2
- ANKK1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 228/495 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs533347208, COSV100392619; called by muse, mutect2
- ANKRD31 | c.5051del p.K1684Rfs*3 | Frame Shift Del (DEL) | VAF 109/251 reads (43%) | catalogued as rs1266122027; called by mutect2, pindel, varscan2
- ANKRD36C | c.3688G>A p.V1230I | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.775); catalogued as rs966984145; called by muse, mutect2, varscan2
- ANO1 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 188/385 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs557778881; called by muse, mutect2, varscan2
- AP1G2 | c.2166G>C p.Q722H | Missense Mutation (SNP) | VAF 84/167 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV55338173; called by muse, mutect2, varscan2
- AP2A1 | c.2200G>A p.G734S | Missense Mutation (SNP) | VAF 163/330 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.103); catalogued as rs771647244; called by muse, mutect2, varscan2
- AP3B1 | c.600C>G p.S200R | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.348); catalogued as rs1245456737; called by muse, mutect2, varscan2
- APOBEC3D | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs375389371; called by muse, mutect2, varscan2
- APOL2 | c.515T>C p.V172A | Missense Mutation (SNP) | VAF 156/278 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778573617; called by muse, mutect2, varscan2
- ARHGAP10 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 124/232 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs755933496; called by muse, mutect2, varscan2
- ARHGAP20 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 146/315 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52812295; called by muse, mutect2, varscan2
- ARHGAP35 | c.2521C>T p.H841Y | Missense Mutation (SNP) | VAF 135/285 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101351276; called by muse, mutect2, varscan2
- ARHGEF18 | c.2101C>T p.R701* (on ENST00000359920 / NM_001130955.2; = p.R597* on NM_015318.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 163/376 reads (43%) | catalogued as COSV60469496; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 186/357 reads (52%) | catalogued as rs758608743; called by mutect2, varscan2
- ARID1B | c.3749G>A p.G1250D | Missense Mutation (SNP) | VAF 140/315 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV51661025; called by muse, mutect2, varscan2
- ARMH1 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 107/205 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); catalogued as rs1284096651; called by muse, mutect2, varscan2
- ARSI | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 213/460 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs776520005, COSV60817216; called by muse, mutect2, varscan2
- ASS1 | c.1208A>G p.H403R | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.42); catalogued as rs964964749; called by muse, mutect2, varscan2
- ASTE1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 158/333 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308492071, COSV53908986; called by muse, mutect2, varscan2
- ASTN1 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 228/477 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1426059581; called by muse, mutect2, varscan2
- ATN1 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 206/421 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63110676; called by muse, mutect2, varscan2
- ATP2A1 | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 180/396 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs148957878; called by muse, mutect2, varscan2
- ATP2C2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867841945; called by muse, mutect2, varscan2
- ATP4A | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 187/422 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); catalogued as rs904563816, COSV52871892; called by muse, mutect2, varscan2
- ATP5F1A | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 153/306 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.098); catalogued as rs776215108, COSV56359787; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1185del p.Y396Tfs*12 | Frame Shift Del (DEL) | VAF 87/232 reads (38%) | catalogued as rs566440675, CD023240; called by mutect2, pindel, varscan2
- B4GALNT3 | c.2535-1G>A p.X845_splice | Splice Site (SNP) | VAF 107/240 reads (45%) | catalogued as rs755644051; called by muse, mutect2, varscan2
- BACE1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 172/350 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs768997413, COSV57284157; called by muse, mutect2, varscan2
- BAZ1A | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 152/351 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781435364; called by muse, mutect2, varscan2
- BCL9 | c.3128G>A p.R1043H | Missense Mutation (SNP) | VAF 157/288 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782428890; called by muse, mutect2, varscan2
- BICDL1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 98/231 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777581211, COSV66908375; called by muse, mutect2, varscan2
- BMP6 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 249/529 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1413525977; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 155/384 reads (40%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BOD1L1 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 98/160 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1025310424; called by muse, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 91/400 reads (23%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- C16orf78 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 107/242 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs373637026, COSV54558555; called by muse, mutect2, varscan2
- C2CD4D | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 253/538 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63256114; called by muse, mutect2, varscan2
- C3 | c.4951G>A p.A1651T | Missense Mutation (SNP) | VAF 188/453 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs756442896; called by muse, mutect2
- C6orf15 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 236/487 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs199527614; called by muse, mutect2, varscan2
- CACNA1B | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 216/835 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV53114810; called by muse, mutect2, varscan2
- CACNA2D3 | c.2634del p.F878Lfs*8 | Frame Shift Del (DEL) | VAF 66/176 reads (38%) | catalogued as rs912442024; called by mutect2, pindel, varscan2
- CAMKK2 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 202/384 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763906764; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 94/180 reads (52%) | catalogued as rs765105588; called by mutect2, varscan2
- CAT | c.1119A>G p.I373M | Missense Mutation (SNP) | VAF 174/393 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99573346; called by muse, mutect2
- CCDC130 | c.1007_1008del p.C336Sfs*6 | Frame Shift Del (DEL) | VAF 268/679 reads (39%) | catalogued as rs772130540; called by mutect2, pindel, varscan2
- CCDC22 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 211/439 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as rs782566464; called by muse, mutect2, varscan2
- CCDC27 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 129/288 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs560903163, COSV53899839; called by muse, mutect2, varscan2
- CCDC39 | c.1711A>G p.T571A | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56496115; called by muse, mutect2, varscan2
- CCDC69 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs574161078, COSV62599268; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 96/180 reads (53%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC88A | c.2335del p.I779Sfs*4 | Frame Shift Del (DEL) | VAF 104/274 reads (38%) | catalogued as COSV55059558; called by mutect2, pindel, varscan2
- CDC14A | c.375dup p.Y126Lfs*35 | Frame Shift Ins (INS) | VAF 76/168 reads (45%) | catalogued as rs773911500; called by mutect2, varscan2
- CDC40 | c.870C>T p.G290= | Splice Region (SNP) | VAF 60/180 reads (33%) | catalogued as rs559751620, COSV57010223; called by muse, mutect2, varscan2
- CDH1 | c.2275G>T p.G759* | Nonsense Mutation (SNP) | VAF 65/152 reads (43%) | catalogued as HM080069; called by muse, mutect2, varscan2
- CDH9 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1340493492, COSV50251915; called by muse, mutect2
- CDK11A | c.1777G>A p.A593T (on ENST00000378633 / NM_001313896.2; = p.A590T on NM_024011.4) | Missense Mutation (SNP) | VAF 188/394 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs558730635, COSV52307946; called by muse, mutect2, varscan2
- CDK9 | c.627del p.I210Lfs*66 | Frame Shift Del (DEL) | VAF 174/451 reads (39%) | catalogued as rs755440676; called by mutect2, pindel, varscan2
- CELA2B | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 95/206 reads (46%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as rs751797790, COSV65546054; called by muse, mutect2, varscan2
- CEP57L1 | c.461A>G p.Q154R | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1214056526; called by muse, mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 70/132 reads (53%) | catalogued as rs747064410; called by mutect2, varscan2
- CERS2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 151/343 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1355471060; called by muse, mutect2, varscan2
- CFAP100 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 54/477 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100729163; called by muse, mutect2, varscan2
- CFAP54 | c.3700del p.M1234Cfs*31 | Frame Shift Del (DEL) | VAF 44/168 reads (26%) | catalogued as rs1208977502; called by mutect2, pindel, varscan2
- CFAP69 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 93/193 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs375665829, COSV60185206; called by muse, varscan2
- CHKB | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 108/249 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180051901; called by muse, mutect2, varscan2
- CIITA | c.1962del p.A656Pfs*30 | Frame Shift Del (DEL) | VAF 203/688 reads (30%) | catalogued as COSV60863473; called by pindel, varscan2*
- CLCA1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 135/245 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.696); catalogued as rs780698919, COSV52332156; called by muse, mutect2, varscan2
- CLCN1 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 173/331 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754440141, COSV58372457; called by muse, mutect2, varscan2
- CLCN5 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 140/263 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs372219090; called by muse, mutect2, varscan2
- CNOT6L | c.665del p.K222Rfs*33 (on ENST00000504123 / NM_001286790.2; = p.K217Rfs*33 on NM_144571.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 100/307 reads (33%) | catalogued as COSV53703147; called by pindel, varscan2
- CNTD1 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 104/252 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV100162189; called by muse, mutect2, varscan2
- CNTNAP4 | c.3444A>G p.E1148= | Splice Region (SNP) | VAF 34/222 reads (15%) | catalogued as rs773269330, COSV56683827; called by muse, mutect2, varscan2
- COL26A1 | c.1130G>A p.R377Q (on ENST00000313669 / NM_001278563.3; = p.R375Q on NM_133457.4) | Missense Mutation (SNP) | VAF 159/328 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs762392368; called by muse, mutect2, varscan2
- COL28A1 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 127/254 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs921919913; called by muse, mutect2, varscan2
- CORIN | c.3055G>A p.V1019I | Missense Mutation (SNP) | VAF 171/329 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs749607630, COSV56689560; called by muse, mutect2, varscan2
- CP | c.2137T>C p.Y713H | Missense Mutation (SNP) | VAF 121/280 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764543027; called by muse, mutect2, varscan2
- CPXM1 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 111/289 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs773155636, COSV66045533; called by muse, mutect2, varscan2
- CRB1 | c.2883A>G p.I961M | Missense Mutation (SNP) | VAF 91/188 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as COSV66335115; called by muse, mutect2, varscan2
- CRB2 | c.533del p.G178Afs*266 | Frame Shift Del (DEL) | VAF 226/583 reads (39%) | catalogued as COSV63502798; called by mutect2, pindel, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 117/242 reads (48%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CRYGD | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 120/260 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV52205653; called by muse, mutect2, varscan2
- CSMD1 | c.7621G>T p.D2541Y (on ENST00000520002; = p.D2540Y on NM_033225.6) | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100156102, COSV59356026; called by mutect2, varscan2
- CSMD3 | c.7682G>A p.R2561Q (on ENST00000297405 / NM_001363185.1; = p.R2457Q on NM_052900.3) | Missense Mutation (SNP) | VAF 103/170 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as rs750618214, COSV52169321, COSV52276730; called by muse, mutect2, varscan2
- CTAGE1 | c.2222del p.P741Qfs*15 | Frame Shift Del (DEL) | VAF 94/227 reads (41%) | catalogued as rs771653179; called by mutect2, pindel, varscan2
- CTSA | c.990del p.C331Afs*36 | Frame Shift Del (DEL) | VAF 194/489 reads (40%) | catalogued as rs758642867; called by mutect2, pindel, varscan2
- CUEDC1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 163/343 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1340936408; called by muse, mutect2, varscan2
- CUL9 | c.5587C>T p.R1863* | Nonsense Mutation (SNP) | VAF 154/302 reads (51%) | catalogued as rs778914565, COSV52724790; called by muse, mutect2, varscan2
- CUX1 | c.4316C>T p.P1439L | Missense Mutation (SNP) | VAF 18/501 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs781788885; called by muse, mutect2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 50/138 reads (36%) | catalogued as rs772257590; called by mutect2, varscan2
- CYBRD1 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 201/459 reads (44%) | SIFT tolerated (1); PolyPhen probably damaging (0.976); catalogued as rs1354258450; called by muse, mutect2, varscan2
- CYP4F12 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs760721349; called by muse, mutect2, varscan2
- CYREN | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs774449769, COSV51966250; called by muse, mutect2, varscan2
- CYSLTR2 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 140/289 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs1012003418; called by muse, mutect2, varscan2
- DAGLA | c.1163A>G p.H388R | Missense Mutation (SNP) | VAF 176/346 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs769565314; called by muse, mutect2, varscan2
- DCAF1 | c.2809dup p.Q937Pfs*20 | Frame Shift Ins (INS) | VAF 144/315 reads (46%) | catalogued as rs782606429; called by mutect2, varscan2
- DCAF12L2 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 215/518 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV63584305; called by muse, mutect2, varscan2
- DCHS1 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 172/408 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.321); catalogued as rs775346697, COSV100202303, COSV55034407; called by muse, mutect2, varscan2
- DDB2 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 160/322 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs761699363, COSV99921639; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGKZ | c.1344_1345insC p.K449Qfs*17 (on ENST00000454345 / NM_001105540.2; = p.K261Qfs*17 on NM_003646.4) | Frame Shift Ins (INS) | VAF 46/262 reads (18%) | catalogued as COSV58984107, COSV58987748; called by mutect2, pindel, varscan2
- DIAPH1 | c.2108del p.P703Hfs*65 | Frame Shift Del (DEL) | VAF 44/119 reads (37%) | catalogued as rs771360300; called by mutect2, varscan2
- DLX3 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 254/532 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1032099378, COSV71547429; called by muse, varscan2
- DNAH1 | c.7864C>T p.R2622* | Nonsense Mutation (SNP) | VAF 157/338 reads (46%) | catalogued as rs368033879; called by muse, mutect2, varscan2
- DNAH5 | c.9802G>A p.A3268T | Missense Mutation (SNP) | VAF 195/418 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.141); catalogued as rs1327288599, COSV54213938; called by muse, mutect2, varscan2
- DNAJC21 | c.1155dup p.Q386Tfs*52 | Frame Shift Ins (INS) | VAF 60/204 reads (29%) | catalogued as rs761105777; called by pindel, varscan2
- DOP1B | c.2680A>G p.T894A | Missense Mutation (SNP) | VAF 150/400 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1248371308; called by muse, mutect2
- DPYD | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as rs778298325, COSV64611188; called by muse, mutect2, varscan2
- DUXA | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 24/249 reads (10%) | catalogued as COSV73729711, COSV73729754, COSV99081888; called by muse, mutect2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 48/138 reads (35%) | catalogued as rs751377941; called by mutect2, varscan2
- DZIP1L | c.1835C>T p.T612M | Missense Mutation (SNP) | VAF 115/214 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772148042; called by muse, mutect2, varscan2
- E2F7 | c.177dup p.F60Ifs*12 | Frame Shift Ins (INS) | VAF 130/278 reads (47%) | catalogued as rs771114476; called by mutect2, varscan2
- EFCAB5 | c.450del p.K150Nfs*17 | Frame Shift Del (DEL) | VAF 105/212 reads (50%) | catalogued as rs760813779; called by mutect2, varscan2
- EFHC1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 139/326 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs77682973, COSV64135667; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFL8 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 164/360 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs750706339; called by muse, mutect2, varscan2
- EMSY | c.832-1G>A p.X278_splice | Splice Site (SNP) | VAF 78/140 reads (56%) | catalogued as COSV100595959; called by muse, mutect2, varscan2
- ENC1 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 187/379 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs778976207, COSV56628540; called by muse, mutect2, varscan2
- ENPP2 | c.2482C>T p.R828C (on ENST00000075322 / NM_001040092.3; = p.R880C on NM_006209.5) | Missense Mutation (SNP) | VAF 280/439 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752514086; called by muse, mutect2, varscan2
- ERAL1 | c.12del p.S5Afs*12 | Frame Shift Del (DEL) | VAF 128/313 reads (41%) | catalogued as COSV54739178, COSV54739854; called by mutect2, pindel, varscan2
- ERBB3 | c.555del p.C186Vfs*20 | Frame Shift Del (DEL) | VAF 113/257 reads (44%) | catalogued as COSV57246480; called by mutect2, pindel, varscan2
- ERBB3 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 107/268 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs373609369; called by muse, mutect2, varscan2
- ERN2 | c.2602C>T p.R868* | Nonsense Mutation (SNP) | VAF 179/328 reads (55%) | catalogued as rs755206735, COSV55622362; called by muse, mutect2, varscan2
- ETV4 | c.399dup p.R134Qfs*49 | Frame Shift Ins (INS) | VAF 106/253 reads (42%) | catalogued as rs745944421; called by mutect2, varscan2
- EWSR1 | c.295_297del p.D99del | In Frame Del (DEL) | VAF 162/348 reads (47%) | catalogued as rs769502605; called by mutect2, pindel, varscan2
- EXOC3L1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 198/382 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.068); catalogued as COSV52048739; called by muse, varscan2
- EXOC7 | c.1742A>G p.Y581C (on ENST00000335146 / NM_001145297.4; = p.Y499C on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/264 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs1420829671; called by muse, mutect2, varscan2
- FAM13A | c.3011C>T p.A1004V | Missense Mutation (SNP) | VAF 100/243 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767274249, COSV52015589; called by muse, mutect2, varscan2
- FAM161B | c.361G>A p.D121N (on ENST00000651776; = p.D58N on NM_152445.3) | Missense Mutation (SNP) | VAF 157/329 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV53180126; called by muse, mutect2, varscan2
- FAM83F | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 173/378 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs762446693, COSV60999809; called by muse, mutect2, varscan2
- FASTKD3 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 146/297 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV52947355; called by muse, mutect2, varscan2
- FAT3 | c.4007G>A p.R1336H | Missense Mutation (SNP) | VAF 116/232 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs528757478, COSV53091298; called by muse, mutect2, varscan2
- FBN1 | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 105/215 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751517759, COSV57323743; called by muse, mutect2, varscan2
- FBN2 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 94/185 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748861935, COSV52496325; called by muse, mutect2, varscan2
- FBXO38 | c.2516C>G p.S839C | Missense Mutation (SNP) | VAF 17/481 reads (4%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV57025680; called by muse, mutect2
- FBXW7 | c.1730T>C p.L577S (on ENST00000281708 / NM_001349798.2; = p.L497S on NM_018315.5) | Missense Mutation (SNP) | VAF 133/289 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99653583; called by muse, mutect2, varscan2
- FCGR3A | c.608T>C p.F203S | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.24); catalogued as rs1042206; called by muse, varscan2
- FHDC1 | c.2932A>G p.R978G | Missense Mutation (SNP) | VAF 214/414 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.395); catalogued as rs533012767; called by muse, mutect2, varscan2
- FMN2 | c.3116C>T p.A1039V | Missense Mutation (SNP) | VAF 54/395 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1188064102, COSV60425744; called by muse, varscan2
- FNIP2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 163/316 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1243318157; called by muse, mutect2, varscan2
- FOXO3 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 184/404 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as rs1245687963, COSV100670216; called by muse, varscan2
- FRMD6 | c.995G>A p.R332H (on ENST00000344768 / NM_001267046.2; = p.R324H on NM_152330.4) | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs779119262, COSV61087328; called by muse, mutect2, varscan2
- FXR2 | c.1619dup p.A541Sfs*14 | Frame Shift Ins (INS) | VAF 176/395 reads (45%) | catalogued as rs753982098; called by mutect2, varscan2
- GBA | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 132/323 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.267); catalogued as rs1169582137; called by muse, mutect2, varscan2
- GCNT4 | c.880del p.H294Ifs*14 | Frame Shift Del (DEL) | VAF 120/308 reads (39%) | catalogued as rs768450027; called by mutect2, pindel, varscan2
- GEMIN4 | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 32/471 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.194); catalogued as rs1170886363; called by muse, mutect2
- GLB1 | c.2006dup p.N669Kfs*53 | Frame Shift Ins (INS) | VAF 58/153 reads (38%) | catalogued as rs759633494; called by mutect2, varscan2
- GLRA3 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 121/255 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as rs138454135; called by muse, mutect2, varscan2
- GLYATL2 | c.268T>C p.S90P | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as COSV54849449; called by muse, mutect2
- GOLGA3 | c.709del p.T237Lfs*37 | Frame Shift Del (DEL) | VAF 190/450 reads (42%) | catalogued as rs143503197; called by mutect2, pindel, varscan2
- GPAA1 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 200/514 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as rs369331503; called by muse, mutect2, varscan2
- GPATCH2L | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 106/237 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.095); catalogued as rs1210981161, COSV55048787; called by muse, mutect2, varscan2
- GPM6B | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 266/497 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.129); catalogued as rs1273493358, COSV100366463; called by muse, mutect2, varscan2
- GPR162 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 235/472 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs782148352; called by muse, mutect2, varscan2
- GPR18 | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 130/253 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs755906704; called by muse, mutect2, varscan2
- GREB1L | c.4016G>A p.R1339H | Missense Mutation (SNP) | VAF 126/275 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368919544; called by muse, mutect2, varscan2
- GRHL3 | c.1151G>A p.G384D (on ENST00000350501 / NM_198174.3; = p.G389D on NM_021180.3) | Missense Mutation (SNP) | VAF 156/318 reads (49%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.792); catalogued as rs199589207; called by muse, mutect2, varscan2
- GRIK5 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 248/514 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as rs1428033252; called by muse, mutect2, varscan2
- GRM4 | c.2462C>T p.T821M | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs760667044; called by muse, mutect2, varscan2
- GRM6 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 240/466 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.464); catalogued as rs150850494; called by muse, mutect2, varscan2
- H3-4 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 165/325 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.155); catalogued as rs756810829; called by muse, mutect2, varscan2
- HCN4 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 163/339 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs998387579, COSV56086816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HECW2 | c.3494G>A p.R1165H | Missense Mutation (SNP) | VAF 92/173 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs750140467; called by muse, mutect2, varscan2
- HECW2 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 116/283 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs143599492; called by muse, mutect2, varscan2
- HHAT | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 118/270 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs376491664; called by muse, mutect2, varscan2
- HNRNPD | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 120/275 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58313307; called by muse, mutect2, varscan2
- HPS1 | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 146/348 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as rs1402316024; called by muse, mutect2, varscan2
- HRH1 | c.625T>C p.F209L | Missense Mutation (SNP) | VAF 196/379 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.394); catalogued as rs201101191; called by muse, mutect2, varscan2
- HSPG2 | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 104/242 reads (43%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.515); catalogued as rs751663070, COSV65978320; called by muse, mutect2, varscan2
- ICE1 | c.6444G>C p.W2148C | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56827302, COSV99665693; called by muse, mutect2, varscan2
- IGKV4-1 | c.301A>T p.I101F | Missense Mutation (SNP) | VAF 125/269 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs182919936; called by muse, mutect2, varscan2
- IGLON5 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 149/310 reads (48%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.975); catalogued as rs1233098171, COSV54538838; called by muse, mutect2, varscan2
- IL1RAP | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 134/254 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs142111398; called by muse, mutect2, varscan2
- IL6ST | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs146382783; called by muse, mutect2, varscan2
- INTS14 | c.971C>T p.A324V (on ENST00000313182 / NM_001366360.2; = p.A245V on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/223 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs771085186; called by muse, mutect2, varscan2
- IP6K2 | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 190/358 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV104409081; called by muse, mutect2, varscan2
- IQSEC2 | c.3053C>T p.T1018M (on ENST00000642864 / NM_001111125.3; = p.T813M on NM_015075.2) | Missense Mutation (SNP) | VAF 10/311 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV64723920; called by muse, mutect2
- ISLR2 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 237/493 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1245525710; called by muse, mutect2, varscan2
- ITGA5 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 301/592 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs756815283, COSV53216035; called by mutect2, varscan2
- ITIH1 | c.2004C>T p.G668= | Splice Region (SNP) | VAF 132/299 reads (44%) | catalogued as rs781432704; called by muse, mutect2, varscan2
- ITSN1 | c.3286G>A p.A1096T | Missense Mutation (SNP) | VAF 116/214 reads (54%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs764397454; called by muse, mutect2, varscan2
- JAKMIP3 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs142581576; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.776-1G>A p.X259_splice | Splice Site (SNP) | VAF 107/226 reads (47%) | catalogued as rs547246053; called by muse, mutect2, varscan2
- KALRN | c.6812C>T p.A2271V (on ENST00000360013 / NM_001024660.4; = p.A574V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/255 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs753999093, COSV99360822; called by muse, mutect2, varscan2
- KBTBD11 | c.1457G>A p.S486N | Missense Mutation (SNP) | VAF 158/582 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.028); catalogued as rs1172647502; called by muse, varscan2
- KBTBD8 | c.1271_1274del p.V424Afs*40 | Frame Shift Del (DEL) | VAF 104/269 reads (39%) | catalogued as rs756313780; called by mutect2, pindel, varscan2
- KCNA5 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 365/675 reads (54%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1357336410, COSV99363815; called by muse, mutect2, varscan2
- KCNT1 | c.1556G>A p.R519H (on ENST00000488444; = p.R538H on NM_020822.3) | Missense Mutation (SNP) | VAF 69/424 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs748178951; called by muse, mutect2, varscan2
- KCTD16 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 176/371 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs148474129; called by muse, mutect2, varscan2
- KDM4D | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 159/328 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200053257; called by muse, mutect2, varscan2
- KDM6B | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 162/336 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.37); catalogued as COSV54683544, COSV54684648; called by muse, mutect2, varscan2
- KDM6B | c.3358G>A p.A1120T | Missense Mutation (SNP) | VAF 185/368 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs1300689796, COSV99642321; called by muse, mutect2, varscan2
- KDM7A | c.2758A>G p.T920A | Missense Mutation (SNP) | VAF 136/300 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1238551112; called by muse, mutect2, varscan2
- KHDRBS2 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 163/344 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.191); catalogued as rs372434154; called by muse, mutect2, varscan2
- KIF1C | c.3265C>T p.R1089W | Missense Mutation (SNP) | VAF 166/323 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs780451511; called by muse, mutect2, varscan2
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 38/103 reads (37%) | catalogued as rs753332734; called by mutect2, varscan2
- KIF26B | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 196/432 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1002374622; called by muse, mutect2, varscan2
- KIRREL2 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 124/221 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs1412996071, COSV52875112; called by muse, mutect2, varscan2
- KLC2 | c.1708del p.Q570Rfs*8 | Frame Shift Del (DEL) | VAF 160/379 reads (42%) | catalogued as rs1183967253, COSV57581594; called by mutect2, pindel, varscan2
- KLHDC7A | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 263/598 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1163496585; called by muse, mutect2, varscan2
- KLHL2 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442388297, COSV56974886; called by muse, mutect2, varscan2
- KLHL38 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 173/546 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as rs375130098; called by muse, mutect2, varscan2
- KMT2B | c.5425G>A p.A1809T | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs377420237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT33B | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 142/331 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs750809007, COSV52440042; called by muse, mutect2, varscan2
- KRT5 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 111/260 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs56729325, CM062802; ClinVar: not provided; called by muse, mutect2, varscan2
- KSR2 | c.1606dup p.L536Pfs*4 | Frame Shift Ins (INS) | VAF 258/574 reads (45%) | catalogued as rs770565486; called by mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 86/210 reads (41%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LATS2 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 92/219 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs746455173, COSV66879317; called by muse, mutect2, varscan2
- LCE3B | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 152/152 reads (100%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs762003582; called by muse, mutect2, varscan2
- LCLAT1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 166/320 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs374373733; called by muse, mutect2, varscan2
- LCP2 | c.571dup p.Q191Pfs*61 | Frame Shift Ins (INS) | VAF 19/62 reads (31%) | catalogued as rs769342570; called by mutect2, varscan2
- LDOC1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 254/564 reads (45%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.901); catalogued as COSV65159307; called by muse, mutect2, varscan2
- LILRA6 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 160/538 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as rs767009944; called by muse, varscan2
- LONP1 | c.87dup p.R30Afs*116 | Frame Shift Ins (INS) | VAF 176/506 reads (35%) | catalogued as rs1356390604; called by mutect2, pindel, varscan2
- LRP1 | c.2814dup p.N939Qfs*18 | Frame Shift Ins (INS) | VAF 124/278 reads (45%) | catalogued as rs750932259; called by mutect2, varscan2
- LRP1 | c.4829C>T p.T1610M | Missense Mutation (SNP) | VAF 153/312 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1240179235, COSV54528309; called by muse, mutect2, varscan2
- LRP12 | c.1340del p.N447Tfs*41 | Frame Shift Del (DEL) | VAF 231/508 reads (45%) | catalogued as rs1217102319, COSV52630472; called by mutect2, pindel, varscan2
- LRRC43 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 208/437 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs771378312, COSV60288324; called by muse, mutect2, varscan2
- LRRC4B | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 195/456 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as COSV65350474; called by muse, mutect2, varscan2
- LRRC56 | c.728del p.P243Rfs*3 | Frame Shift Del (DEL) | VAF 280/692 reads (40%) | catalogued as rs762528881; called by mutect2, pindel, varscan2
- LRRC8C | c.1524del p.W509Gfs*13 | Frame Shift Del (DEL) | VAF 79/186 reads (42%) | catalogued as rs762972819; called by mutect2, pindel, varscan2
- LRRCC1 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 155/304 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.177); catalogued as rs1158451841; called by muse, mutect2, varscan2
- LRRK1 | c.4942G>A p.A1648T | Missense Mutation (SNP) | VAF 149/302 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs572219729; called by muse, mutect2, varscan2
- LRRK2 | c.953T>C p.L318P | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as COSV100109105; called by muse, mutect2
- LSP1 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 133/265 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs770047466; called by muse, mutect2, varscan2
- LTBP4 | c.3382A>G p.M1128V (on ENST00000308370 / NM_001042544.1; = p.M1091V on NM_003573.2) | Missense Mutation (SNP) | VAF 166/325 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.696); catalogued as rs749783591; called by muse, mutect2, varscan2
- LYAR | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 180/368 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs759335108; called by muse, mutect2, varscan2
- LYST | c.5152C>T p.R1718* | Nonsense Mutation (SNP) | VAF 94/203 reads (46%) | catalogued as rs1412672912, COSV67713807; called by muse, mutect2, varscan2
- MACF1 | c.19621C>T p.R6541* (on ENST00000372915; = p.R4586* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 107/226 reads (47%) | catalogued as COSV57133543; called by muse, mutect2, varscan2
- MAGEA6 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.159); catalogued as rs782541530, COSV100262662; called by muse, mutect2, varscan2
- MAML1 | c.241A>C p.T81P | Missense Mutation (SNP) | VAF 230/531 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1181039293; called by muse, mutect2, varscan2
- MBD6 | c.2104dup p.Q702Pfs*15 | Frame Shift Ins (INS) | VAF 154/402 reads (38%) | catalogued as rs756309560; called by mutect2, pindel, varscan2
- MCM3AP | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 99/303 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as rs776926615, COSV52438112; called by muse, mutect2, varscan2
- MED13L | c.1011T>C p.G337= | Splice Region (SNP) | VAF 79/171 reads (46%) | catalogued as rs1300927555; called by mutect2, varscan2
- MEGF8 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 263/551 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.41); catalogued as rs1437893178, COSV99238267; called by muse, mutect2, varscan2
- MESD | c.632dup p.K212Efs*19 | Frame Shift Ins (INS) | VAF 156/392 reads (40%) | catalogued as rs745891632; called by mutect2, varscan2
- MET | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 124/247 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs986139438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- METTL9 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 88/163 reads (54%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs1288843275; called by muse, mutect2, varscan2
- MIER3 | c.1027del p.R343Dfs*15 (on ENST00000381199 / NM_001297599.2; = p.R342Dfs*15 on NM_152622.4) | Frame Shift Del (DEL) | VAF 108/289 reads (37%) | catalogued as COSV67083276; called by mutect2, pindel, varscan2
- MORC1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs764997031, COSV51718785; called by muse, mutect2, varscan2
- MOV10 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 219/458 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); catalogued as rs755646925, COSV62491432; called by muse, mutect2
- MPDZ | c.4933G>A p.G1645R | Missense Mutation (SNP) | VAF 99/195 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175661788; called by muse, mutect2, varscan2
- MPHOSPH8 | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 152/308 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs765405363; called by muse, mutect2, varscan2
- MRGPRX1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 134/430 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs757338968, COSV57106021; called by muse, mutect2, varscan2
- MRPS31 | c.739del p.R247Gfs*15 | Frame Shift Del (DEL) | VAF 74/156 reads (47%) | catalogued as COSV100062133; called by mutect2, varscan2
- MST1 | c.1288_1290del p.E430del | In Frame Del (DEL) | VAF 142/284 reads (50%) | catalogued as rs751306787; called by pindel, varscan2
- MTURN | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 83/189 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as rs138966019; called by muse, mutect2, varscan2
- MUC16 | c.17212G>T p.A5738S | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.11); catalogued as COSV67456630; called by muse, mutect2, varscan2
- MYH10 | c.5014T>G p.F1672V | Missense Mutation (SNP) | VAF 127/293 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as rs1036161314; called by muse, mutect2, varscan2
- MYH9 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 112/210 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs748614086; called by muse, mutect2, varscan2
- MYO15A | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 121/224 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs527582798, COSV52751289; called by muse, mutect2, varscan2
- MYO15A | c.2830C>T p.P944S | Missense Mutation (SNP) | VAF 199/356 reads (56%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.58); catalogued as rs1259088949; called by muse, mutect2, varscan2
- MYO18B | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 154/330 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1204493003; called by muse, mutect2, varscan2
- MYO1G | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 135/272 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs1208746512; called by muse, mutect2, varscan2
- N4BP2L2 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as rs567381297, COSV57228394; called by muse, mutect2, varscan2
- NAGS | c.654dup p.G219Wfs*77 | Frame Shift Ins (INS) | VAF 234/606 reads (39%) | catalogued as rs1256337877; called by mutect2, pindel, varscan2
- NAT8L | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 140/228 reads (61%) | SIFT tolerated, low confidence (0.58); catalogued as rs1441277282; called by muse, varscan2
- NBAS | c.1898T>C p.I633T | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs767525696; called by muse, mutect2, varscan2
- NCOA2 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 101/197 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs1200478671; called by muse, mutect2, varscan2
- NCOA5 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 220/460 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs756677429; called by muse, mutect2, varscan2
- NCOR1 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.124); catalogued as rs150859090; called by muse, mutect2, varscan2
- NDUFAF1 | c.893T>C p.I298T | Missense Mutation (SNP) | VAF 108/229 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs375783945; called by muse, mutect2, varscan2
- NDUFAF7 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 186/402 reads (46%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as rs1479743929; called by muse, mutect2, varscan2
- NEB | c.12985C>A p.Q4329K | Missense Mutation (SNP) | VAF 112/244 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.209); catalogued as rs750905463; called by muse, mutect2, varscan2
- NECTIN3 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 174/344 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs376114520; called by muse, mutect2, varscan2
- NEMF | c.1760del p.P587Hfs*4 | Frame Shift Del (DEL) | VAF 86/253 reads (34%) | catalogued as COSV53595235; called by pindel, varscan2
- NHS | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 223/458 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs750950128, COSV66271160, COSV66273623; called by muse, mutect2, varscan2
- NIBAN2 | c.1696C>T p.R566W | Missense Mutation (SNP) | VAF 157/357 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754978264; called by muse, mutect2, varscan2
- NKX3-2 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 306/571 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs774148012; called by muse, mutect2, varscan2
- NMBR | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 162/349 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs767510484, COSV57800816; called by muse, mutect2, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 169/182 reads (93%) | catalogued as rs751187638; called by mutect2, varscan2
- NOL9 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 132/282 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100063219; called by muse, varscan2
- NPAP1 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 237/554 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs531772049, COSV61506192, COSV61510653; called by muse, mutect2, varscan2
- NR1D1 | c.671T>C p.M224T | Missense Mutation (SNP) | VAF 176/365 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1385418968, COSV99225917; called by muse, mutect2, varscan2
- NRG3 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 114/224 reads (51%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); catalogued as rs1477136566; called by muse, varscan2
- NRG3 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 339/647 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs1351683889, COSV64568610; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 110/260 reads (42%) | catalogued as rs776154715; called by mutect2, varscan2
- NSD1 | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 131/267 reads (49%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.054); catalogued as rs757909532, CD056831; called by muse, mutect2, varscan2
- NUAK2 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 176/403 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs771322956, COSV65681383; called by muse, mutect2, varscan2
- NUP42 | c.212dup p.S72Qfs*13 | Frame Shift Ins (INS) | VAF 108/244 reads (44%) | catalogued as rs758695627; called by mutect2, varscan2
- NUP88 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 123/289 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563564141, COSV56702610, COSV56708095; called by muse, mutect2, varscan2
- NYX | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 317/649 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs746330892; called by muse, mutect2, varscan2
- OBSL1 | c.3995G>A p.R1332Q | Missense Mutation (SNP) | VAF 295/544 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.416); catalogued as rs1402861976; called by muse, mutect2, varscan2
- OLFM2 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 180/404 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs200443185, COSV53429909; called by muse, varscan2
- OR10G7 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 187/648 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV57867134; called by muse, mutect2, varscan2
- OR10R2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 153/314 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV63769296; called by muse, mutect2, varscan2
- OR13J1 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 139/330 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV65069377; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 149/377 reads (40%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 143/292 reads (49%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52J3 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 166/313 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV66747698; called by muse, mutect2
- OR5I1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 141/299 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1565151589, COSV56887915; called by muse, mutect2, varscan2
- OR6C70 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV100524352, COSV59244835; called by muse, mutect2, varscan2
- OR8K5 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 115/234 reads (49%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV57888333; called by muse, mutect2, varscan2
- OSBP2 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs374035667; called by muse, mutect2, varscan2
- OSBPL11 | c.127A>G p.S43G | Missense Mutation (SNP) | VAF 178/391 reads (46%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs778401944, COSV99953884; called by muse, mutect2, varscan2
- PANK4 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 290/627 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs758176055; called by muse, mutect2, varscan2
- PARP6 | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 139/305 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.368); catalogued as rs749363368; called by muse, mutect2, varscan2
- PATL1 | c.478dup p.Q160Pfs*6 | Frame Shift Ins (INS) | VAF 111/244 reads (45%) | catalogued as rs757903860; called by mutect2, varscan2
- PCCA | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1192444349, COSV66198474; called by muse, mutect2
- PCDHA4 | c.1634T>C p.L545P | Missense Mutation (SNP) | VAF 39/630 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63539054; called by muse, mutect2
- PCDHB10 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 212/722 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1554284424, COSV99504679; called by muse, varscan2
- PCDHB13 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 110/274 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.035); catalogued as rs536260978, COSV99507161; called by muse, mutect2, varscan2
- PCDHB15 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 321/670 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.081); catalogued as rs1224877053, COSV51431200; called by muse, mutect2
- PCDHGB3 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 162/327 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs548499010, COSV53919749; called by muse, mutect2, varscan2
- PCDHGB4 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.02); catalogued as rs1374751231; called by muse, mutect2, varscan2
- PCLO | c.8896C>T p.R2966C | Missense Mutation (SNP) | VAF 204/345 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1173009964, COSV61649863; called by muse, mutect2, varscan2
- PCNX1 | c.4870C>T p.R1624W | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99455488; called by muse, mutect2, varscan2
- PDS5B | c.2630G>A p.R877H | Missense Mutation (SNP) | VAF 93/213 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.596); catalogued as rs1329917777, COSV59733076; called by muse, mutect2, varscan2
- PDZD2 | c.2207G>T p.R736I | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.972); catalogued as COSV56874898; called by muse, mutect2, varscan2
- PDZD2 | c.7973C>T p.A2658V | Missense Mutation (SNP) | VAF 89/207 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.029); catalogued as rs765059618; called by muse, mutect2, varscan2
- PDZD7 | c.2392T>C p.S798P | Missense Mutation (SNP) | VAF 265/587 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs1450346464; called by muse, mutect2
- PEG3 | c.3878A>G p.N1293S | Missense Mutation (SNP) | VAF 147/330 reads (45%) | SIFT tolerated (0.96); PolyPhen benign (0.009); catalogued as rs747830167; called by muse, mutect2, varscan2
- PEX5 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs772215584, COSV99871170; called by muse, varscan2
- PIK3C3 | c.2112dup p.R705* | Frame Shift Ins (INS) | VAF 50/126 reads (40%) | catalogued as rs1234146599; called by mutect2, pindel, varscan2
- PLA2G4C | c.263T>C p.I88T | Missense Mutation (SNP) | VAF 126/241 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs773683002; called by muse, mutect2
- PLXNA1 | c.3308T>C p.V1103A | Missense Mutation (SNP) | VAF 117/475 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.403); catalogued as rs776993963; called by muse, mutect2, varscan2
- PLXNA1 | c.5638C>T p.R1880W | Missense Mutation (SNP) | VAF 186/382 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1368078128, COSV52530596; called by muse, mutect2, varscan2
- PNISR | c.1491del p.E498Sfs*85 | Frame Shift Del (DEL) | VAF 113/287 reads (39%) | catalogued as rs1401239378; called by mutect2, pindel, varscan2
- PNPLA6 | c.2593G>A p.V865M (on ENST00000414982 / NM_001166111.2; = p.V817M on NM_006702.5) | Missense Mutation (SNP) | VAF 133/432 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs144375033; called by muse, mutect2, varscan2
- POLE | c.3475C>T p.P1159S | Missense Mutation (SNP) | VAF 94/240 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57677478; called by muse, varscan2
- POMT2 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 132/279 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as rs201117837; called by muse, mutect2, varscan2
- POP1 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 175/307 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1317275112, COSV62892685; called by muse, mutect2, varscan2
- POTEA | c.1562G>A p.R521H (on ENST00000519951 / NM_001005365.2; = p.R475H on NM_001002920.1) | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1253043177; called by muse, mutect2, varscan2
- POU2F1 | c.1759G>A p.A587T (on ENST00000541643 / NM_001365848.1; = p.A610T on NM_002697.4) | Missense Mutation (SNP) | VAF 124/302 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1483832523; called by muse, mutect2, varscan2
- PPM1G | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 20/459 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1286589585; called by muse, mutect2
- PPP1R13B | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 54/449 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as rs201114467, COSV104390077; called by muse, mutect2, varscan2
- PPP3R2 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 181/374 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1378306586, COSV100701405, COSV62450758; called by muse, mutect2, varscan2
- PROX1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 136/313 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1374775160, COSV99800417; called by muse, mutect2, varscan2
- PRPF6 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 123/257 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.654); catalogued as COSV53870458; called by muse, mutect2, varscan2
- PRPF6 | c.2758G>A p.A920T | Missense Mutation (SNP) | VAF 216/450 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs766740751, COSV53867954; called by muse, mutect2, varscan2
- PRR12 | c.37del p.H13Tfs*66 (on ENST00000615927; = p.P408Hfs*62 on NM_020719.3) | Frame Shift Del (DEL) | VAF 176/400 reads (44%) | catalogued as rs763575972; called by mutect2, varscan2
- PRRC2B | c.6245G>A p.R2082Q | Missense Mutation (SNP) | VAF 160/327 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs756081846, COSV100260894; called by muse, mutect2, varscan2
- PRTG | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 104/228 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV101221280, COSV66838704; called by muse, mutect2, varscan2
- PSG4 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs765839412; called by muse, mutect2, varscan2
- PSMB8 | c.229G>A p.A77T (on ENST00000374882 / NM_148919.4; = p.A73T on NM_004159.5) | Missense Mutation (SNP) | VAF 240/499 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774341327; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSMC1 | c.567del p.L190Wfs*27 | Frame Shift Del (DEL) | VAF 101/232 reads (44%) | catalogued as rs1566672946; called by mutect2, pindel, varscan2
- PTPDC1 | c.2027del p.L676Yfs*2 (on ENST00000375360 / NM_177995.3; = p.L728Yfs*2 on NM_152422.4) | Frame Shift Del (DEL) | VAF 107/260 reads (41%) | catalogued as COSV56622149; called by mutect2, pindel, varscan2
- PTPN5 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 182/384 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62125604, COSV62127725; called by muse, mutect2, varscan2
- RAB11B | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 196/407 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); catalogued as rs373086696; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 173/370 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs560021865; called by muse, mutect2, varscan2
- RAB42 | c.242dup p.V82Cfs*38 | Frame Shift Ins (INS) | VAF 161/336 reads (48%) | catalogued as rs753536519; called by mutect2, varscan2
- RALGAPA2 | c.4534C>G p.Q1512E | Missense Mutation (SNP) | VAF 148/288 reads (51%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV52509724; called by muse, mutect2, varscan2
- RAPGEF4 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 116/254 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs758218304; called by muse, mutect2, varscan2
- RASA1 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 142/298 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs770599456, COSV57200740; called by muse, mutect2, varscan2
- RASSF2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 178/367 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs754308859, COSV65082426; called by muse, varscan2
- RASSF3 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as rs982253222; called by muse, varscan2
- RBBP6 | c.3611C>T p.A1204V | Missense Mutation (SNP) | VAF 137/304 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs760684099, COSV60505418; called by muse, mutect2, varscan2
- RBM12B | c.1118_1120del p.K373del | In Frame Del (DEL) | VAF 174/311 reads (56%) | catalogued as rs764449240; called by pindel, varscan2
- RBM43 | c.213del p.V72Lfs*13 | Frame Shift Del (DEL) | VAF 48/99 reads (48%) | catalogued as rs746242773; called by mutect2, varscan2
- RCAN3 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 152/391 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV65558305; called by muse, mutect2, varscan2
- RCC1 | c.38del p.P13Qfs*11 | Frame Shift Del (DEL) | VAF 173/410 reads (42%) | catalogued as rs746656171; called by mutect2, pindel, varscan2
- RCOR1 | c.190G>C p.A64P | Missense Mutation (SNP) | VAF 169/379 reads (45%) | SIFT tolerated, low confidence (0.3); catalogued as COSV51767462, COSV51772689; called by mutect2, varscan2
- RELCH | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 84/196 reads (43%) | catalogued as COSV56885202; called by muse, mutect2, varscan2
- RFC1 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs374549255, COSV62899615; called by muse, mutect2, varscan2
- RGPD4 | c.4803del p.K1601Nfs*69 | Frame Shift Del (DEL) | VAF 93/229 reads (41%) | catalogued as rs1558816973; called by mutect2, varscan2
- RGS12 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 238/464 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as rs757883420; called by muse, mutect2, varscan2
- RGS20 | c.580G>A p.A194T (on ENST00000297313 / NM_170587.4; = p.A47T on NM_003702.4) | Missense Mutation (SNP) | VAF 226/479 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs745947023, COSV52016381; called by muse, mutect2, varscan2
- RHOT1 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 96/187 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753817381; called by muse, mutect2, varscan2
- RIMBP3 | c.4040T>C p.L1347P | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1568931256; called by muse, mutect2, varscan2
- RIOK1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138314843; called by muse, mutect2, varscan2
- RLBP1 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 229/534 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs761816415, COSV99175352; called by muse, mutect2, varscan2
- RNF165 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 292/606 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1480255890, COSV53976329, COSV53977539; called by muse, varscan2
- ROBO2 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 101/212 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1196957436, COSV59895199; called by muse, mutect2, varscan2
- ROCK2 | c.412del p.W138Gfs*31 | Frame Shift Del (DEL) | VAF 114/304 reads (38%) | catalogued as rs755738345; called by mutect2, pindel, varscan2
- RTP1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 231/467 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs766864382; called by muse, mutect2, varscan2
- RUBCN | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 132/301 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1189739719, COSV56373973; called by muse, mutect2, varscan2
- RUNX1T1 | c.1139G>A p.R380Q (on ENST00000265814 / NM_001198628.1; = p.R353Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/369 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.692); catalogued as rs1242643618, COSV56152543; called by muse, mutect2, varscan2
- RXFP3 | c.1374del p.R459Afs*31 | Frame Shift Del (DEL) | VAF 215/546 reads (39%) | catalogued as COSV57506315; called by mutect2, pindel, varscan2
- RYR3 | c.3997C>T p.R1333C | Missense Mutation (SNP) | VAF 99/204 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs901274242, COSV66778867; called by muse, mutect2, varscan2
- SAMD4A | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 169/341 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs866283168; called by muse, mutect2, varscan2
- SATB1 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 131/247 reads (53%) | catalogued as COSV58668666; called by muse, mutect2, varscan2
- SBF1 | c.3228dup p.S1077Qfs*11 | Frame Shift Ins (INS) | VAF 176/392 reads (45%) | catalogued as rs771002611; called by mutect2, varscan2
- SBSPON | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 248/525 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766329688, COSV52076876; called by muse, mutect2, varscan2
- SCAF8 | c.1832C>T p.T611M | Missense Mutation (SNP) | VAF 114/251 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as rs764803548, COSV63200337; called by muse, varscan2
- SCFD1 | c.1888A>G p.T630A | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1228762720; called by muse, mutect2, varscan2
- SCMH1 | c.823C>T p.R275C (on ENST00000326197 / NM_001031694.2; = p.R228C on NM_012236.4) | Missense Mutation (SNP) | VAF 126/276 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs769479657; called by muse, mutect2, varscan2
- SCNN1D | c.53del p.G18Afs*179 (on ENST00000338555; = p.A151Lfs*18 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 61/196 reads (31%) | catalogued as rs1270083658; called by mutect2, pindel, varscan2
- SCRIB | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 157/447 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.019); catalogued as COSV57590141; called by muse, mutect2, varscan2
- SCUBE3 | c.1654C>A p.L552M | Missense Mutation (SNP) | VAF 126/306 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV51457730; called by muse, mutect2, varscan2
- SDHAF2 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 113/242 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs753474292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC61A1 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 103/218 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as rs867186228, COSV54577994; called by muse, varscan2
- SERPINB13 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 126/249 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs139825462; called by muse, mutect2, varscan2
- SERPINF2 | c.1370T>C p.L457P | Missense Mutation (SNP) | VAF 257/554 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs764347515; called by muse, mutect2, varscan2
- SGSM1 | c.3257C>T p.A1086V (on ENST00000400359 / NM_001039948.4; = p.A1025V on NM_133454.3) | Missense Mutation (SNP) | VAF 174/393 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.345); catalogued as rs376703589; called by muse, mutect2, varscan2
- SH3RF2 | c.1576C>A p.L526I | Missense Mutation (SNP) | VAF 124/265 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV63041521; called by muse, mutect2, varscan2
- SHROOM4 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 212/439 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782031775; called by muse, mutect2, varscan2
- SLC10A1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 94/219 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.627); catalogued as rs202056811, COSV53682184; called by muse, mutect2, varscan2
- SLC12A3 | c.2801G>A p.R934Q (on ENST00000563236 / NM_001126108.2; = p.R943Q on NM_000339.3) | Missense Mutation (SNP) | VAF 100/202 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs56259558; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC20A2 | c.94T>A p.S32T | Missense Mutation (SNP) | VAF 131/269 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778249371; called by muse, mutect2, varscan2
- SLC25A11 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 190/398 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs533954470, COSV52591153; called by muse, mutect2, varscan2
- SLC35B2 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 190/369 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs775017717; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 101/235 reads (43%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC38A4 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373742937; called by muse, mutect2, varscan2
- SLC38A7 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 159/388 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV54704797; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 84/162 reads (52%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC45A4 | c.2080G>A p.V694I (on ENST00000517878 / NM_001286646.2; = p.V643I on NM_001080431.2) | Missense Mutation (SNP) | VAF 290/477 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1296013853, COSV99199147; called by muse, mutect2, varscan2
- SLC4A4 | c.272G>A p.R91H (on ENST00000264485 / NM_001098484.3; = p.R47H on NM_003759.4) | Missense Mutation (SNP) | VAF 162/334 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs746761566, COSV52623106, COSV52630049; called by muse, varscan2
- SLC5A1 | c.1205G>A p.S402N | Missense Mutation (SNP) | VAF 142/327 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs767060839; called by muse, mutect2, varscan2
- SLC7A1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 35/333 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.076); catalogued as rs140858980; called by muse, mutect2, varscan2
- SLC7A9 | c.1309T>C p.Y437H | Missense Mutation (SNP) | VAF 17/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50082858; called by muse, mutect2
- SLX1A | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1170815822; called by mutect2, varscan2
- SMO | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 111/234 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as rs761081288, COSV99976493; called by muse, mutect2, varscan2
- SNRNP70 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 278/555 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs1169669444; called by muse, mutect2, varscan2
- SNX19 | c.1299_1300del p.E433Dfs*17 | Frame Shift Del (DEL) | VAF 152/409 reads (37%) | catalogued as rs758627622; called by pindel, varscan2
- SORCS1 | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 158/338 reads (47%) | SIFT tolerated (0.91); PolyPhen benign (0.06); catalogued as rs762709776, COSV53877057; called by muse, mutect2, varscan2
- SOX14 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 218/436 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.24); catalogued as COSV60162813; called by muse, mutect2, varscan2
- SPAG17 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 112/244 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs750605549, COSV60463634; called by muse, mutect2, varscan2
- SPSB4 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 183/401 reads (46%) | catalogued as rs1449352418, COSV100140975; called by muse, mutect2, varscan2
- SPTBN2 | c.4700A>G p.Q1567R | Missense Mutation (SNP) | VAF 319/610 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs779667441; called by muse, mutect2, varscan2
- SPTBN4 | c.2746G>A p.V916I | Missense Mutation (SNP) | VAF 121/236 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as rs1199121067; called by muse, mutect2, varscan2
- SPTBN4 | c.5693C>T p.A1898V | Missense Mutation (SNP) | VAF 178/367 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1393665116; called by muse, mutect2, varscan2
- SRBD1 | c.683T>G p.V228G | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV55396710; called by muse, mutect2, varscan2
- SRCAP | c.4100C>T p.T1367I | Missense Mutation (SNP) | VAF 193/405 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as rs140099605; called by muse, mutect2, varscan2
- SRGAP2 | c.2006C>T p.T669I (on ENST00000624873 / NM_001170637.4; = p.T670I on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/367 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1350654679; called by muse, mutect2, varscan2
- SRL | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 133/276 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs374318073, COSV68422883; called by muse, mutect2, varscan2
- SSTR1 | c.973T>C p.F325L | Missense Mutation (SNP) | VAF 197/364 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as rs1248209556; called by muse, mutect2, varscan2
- ST6GAL1 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 115/211 reads (55%) | PolyPhen probably damaging (0.997); catalogued as rs770609191; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 76/168 reads (45%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STK10 | c.1754A>G p.N585S | Missense Mutation (SNP) | VAF 163/289 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1021492041; called by muse, mutect2, varscan2
- STRA6 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 152/319 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs773673476; called by muse, mutect2, varscan2
- STX8 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs762638614, COSV60487852; called by muse, mutect2, varscan2
- SULF2 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 128/241 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.238); catalogued as rs375580969; called by muse, varscan2
- SULT1B1 | c.575del p.L192Cfs*6 | Frame Shift Del (DEL) | VAF 86/212 reads (41%) | catalogued as rs1316574540; called by mutect2, pindel, varscan2
- SUN5 | c.770A>G p.D257G | Missense Mutation (SNP) | VAF 168/309 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs143463447; called by muse, mutect2, varscan2
- SVOPL | c.1417G>A p.A473T (on ENST00000419765; = p.A321T on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.68); catalogued as rs776814871, COSV55990782; called by muse, mutect2, varscan2
- SYNE1 | c.19973A>G p.K6658R (on ENST00000367255 / NM_182961.4; = p.K6587R on NM_033071.3) | Missense Mutation (SNP) | VAF 120/284 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV54917898; called by muse, varscan2
- TAF1C | c.2419G>A p.V807I | Missense Mutation (SNP) | VAF 241/536 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs148942327; called by muse, mutect2, varscan2
- TAF1C | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 224/500 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs745621785; called by muse, mutect2, varscan2
- TBL1XR1 | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104420670, COSV61793089; called by muse, mutect2, varscan2
- TCF7 | c.983T>C p.L328P | Missense Mutation (SNP) | VAF 146/304 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58656029; called by muse, mutect2, varscan2
- TCOF1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 136/328 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as CD160705; called by muse, mutect2, varscan2
- TDRD5 | c.1236dup p.Q413Tfs*13 | Frame Shift Ins (INS) | VAF 112/240 reads (47%) | catalogued as rs1433075758; called by mutect2, varscan2
- TENM4 | c.3097A>G p.S1033G | Missense Mutation (SNP) | VAF 127/294 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376631231; called by muse, mutect2, varscan2
- TET2 | c.4317dup p.R1440Tfs*38 | Frame Shift Ins (INS) | VAF 154/392 reads (39%) | catalogued as rs777908833; called by mutect2, pindel, varscan2
- TEX35 | c.589A>T p.N197Y | Missense Mutation (SNP) | VAF 95/184 reads (52%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.037); catalogued as rs1201532818; called by muse, mutect2, varscan2
- TGFBRAP1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 104/230 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.91); catalogued as rs560629083; called by muse, mutect2, varscan2
- THRAP3 | c.1244G>T p.R415L | Missense Mutation (SNP) | VAF 135/286 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs758097583, COSV100663380; called by muse, mutect2, varscan2
- TIMM29 | c.724_726del p.K242del | In Frame Del (DEL) | VAF 114/304 reads (38%) | catalogued as rs761677271; called by pindel, varscan2
- TLL2 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 174/376 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553324585; called by muse, mutect2, varscan2
- TM2D1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs778917284, COSV53908093; called by muse, mutect2, varscan2
- TMA16 | c.45del p.V16Sfs*25 | Frame Shift Del (DEL) | VAF 78/162 reads (48%) | catalogued as rs570113265, COSV62187391; called by mutect2, varscan2
- TMC2 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs112491668; called by muse, varscan2
- TMEM129 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.2); catalogued as rs1029861329; called by muse, mutect2
- TMEM30B | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 226/489 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749903965; called by muse, mutect2, varscan2
- TMEM38B | c.286dup p.C96Lfs*4 | Frame Shift Ins (INS) | VAF 54/133 reads (41%) | catalogued as rs756048916; called by mutect2, varscan2
- TMEM41B | c.758A>G p.Q253R | Missense Mutation (SNP) | VAF 19/332 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV100215872; called by muse, mutect2
- TMEM87A | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.041); catalogued as rs544107092; called by muse, mutect2, varscan2
- TNPO1 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV61521396; called by muse, mutect2, varscan2
- TNPO2 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 185/352 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1158223192; called by muse, mutect2, varscan2
- TNRC6A | c.3364A>G p.M1122V | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1167823140; called by muse, mutect2
- TNS3 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV60786275, COSV60794884; called by muse, mutect2, varscan2
- TNXB | c.12163C>T p.R4055W (on ENST00000647633; = p.R3808W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 206/443 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs149197999; called by muse, mutect2, varscan2
- TP53BP1 | c.4208G>A p.R1403H | Missense Mutation (SNP) | VAF 171/345 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1392592073, COSV99781004; called by muse, mutect2, varscan2
- TPCN2 | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 80/298 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754349694; called by muse, mutect2, varscan2
- TPTE | c.566+1G>A p.X189_splice (on ENST00000618007 / NM_199261.4; = p.X171_splice on NM_199259.4) | Splice Site (SNP) | VAF 49/165 reads (30%) | catalogued as rs751273683; called by muse, mutect2, varscan2
- TRIM35 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 199/389 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.158); catalogued as rs766345697, COSV59522473; called by muse, mutect2, varscan2
- TRIM50 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 192/413 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782766082, COSV53090983; called by muse, mutect2, varscan2
- TRIO | c.6904A>G p.S2302G | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs758154355; called by muse, varscan2
- TRIOBP | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 154/733 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs553427948, COSV60381998; called by muse, mutect2, varscan2
- TRNAU1AP | c.386T>C p.V129A | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs1469745489; called by muse, mutect2, varscan2
- TRPC3 | c.119G>A p.W40* | Nonsense Mutation (SNP) | VAF 334/706 reads (47%) | catalogued as rs1421560760; called by muse, mutect2
- TRPM4 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 135/273 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs183306159; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPV5 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 264/545 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs145819800; called by muse, mutect2, varscan2
- TSPYL5 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 222/614 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1409506792, COSV59070965; called by muse, varscan2
- TTN | c.87908G>A p.R29303H (on ENST00000591111; = p.R21879H on NM_003319.4) | Missense Mutation (SNP) | VAF 125/254 reads (49%) | PolyPhen benign (0.033); catalogued as rs755972883, COSV59881537; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.47039G>A p.R15680H (on ENST00000591111; = p.R8256H on NM_003319.4) | Missense Mutation (SNP) | VAF 114/216 reads (53%) | PolyPhen probably damaging (0.998); catalogued as rs530304166; called by muse, mutect2, varscan2
- TTN | c.42243G>T p.Q14081H (on ENST00000591111; = p.Q6657H on NM_003319.4) | Missense Mutation (SNP) | VAF 152/333 reads (46%) | PolyPhen benign (0.135); catalogued as COSV59903304, COSV60249250; called by muse, mutect2, varscan2
- TUBB6 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 216/418 reads (52%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.99); catalogued as COSV52315198; called by muse, mutect2, varscan2
- TYK2 | c.2996A>G p.Q999R | Missense Mutation (SNP) | VAF 229/521 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as COSV53388416; called by muse, mutect2, varscan2
- TYK2 | c.2203G>A p.V735M | Missense Mutation (SNP) | VAF 144/308 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1473534133; called by muse, mutect2, varscan2
- UBB | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1167091586; called by muse, mutect2
- UNC13D | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 173/364 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs201600711, CM060501; called by muse, mutect2, varscan2
- UNC80 | c.6413T>C p.I2138T | Missense Mutation (SNP) | VAF 128/261 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs1025505186; called by muse, mutect2, varscan2
- UPF3B | c.815G>T p.R272M | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as COSV52231389; called by muse, mutect2, varscan2
- USH2A | c.8957A>G p.H2986R | Missense Mutation (SNP) | VAF 129/293 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV100237039; called by muse, mutect2, varscan2
- VCP | c.1163T>C p.M388T | Missense Mutation (SNP) | VAF 131/266 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV62722479; called by muse, mutect2, varscan2
- VDR | c.1196A>G p.K399R | Missense Mutation (SNP) | VAF 64/498 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.11); catalogued as COSV57470478; called by muse, mutect2, varscan2
- VPS11 | c.752G>A p.R251Q (on ENST00000620429; = p.R795Q on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 142/346 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs782494287; called by muse, mutect2, varscan2
- VPS13D | c.8030C>T p.A2677V | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1479723258, COSV99169628; called by muse, mutect2, varscan2
- VPS33A | c.246del p.F82Lfs*6 | Frame Shift Del (DEL) | VAF 94/194 reads (48%) | catalogued as rs756221452; called by mutect2, varscan2
- VSIG8 | c.1231G>C p.G411R | Missense Mutation (SNP) | VAF 198/386 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63653458; called by muse, mutect2, varscan2
- VWA1 | c.462del p.M155Cfs*51 | Frame Shift Del (DEL) | VAF 204/493 reads (41%) | catalogued as rs760281341; called by mutect2, pindel, varscan2
- VWA5B2 | c.2260C>T p.R754* | Nonsense Mutation (SNP) | VAF 250/487 reads (51%) | catalogued as rs1433368797, COSV56611739; called by muse, mutect2, varscan2
- WDFY4 | c.8923C>T p.R2975W | Missense Mutation (SNP) | VAF 111/242 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs376524309; called by muse, mutect2, varscan2
- WDR90 | c.3031G>C p.A1011P | Missense Mutation (SNP) | VAF 152/322 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs368701693, COSV53470820; called by mutect2, varscan2
- WFS1 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 161/360 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs368236000, COSV99901395; called by muse, varscan2
- WIPF3 | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 81/166 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1352738718; called by muse, mutect2, varscan2
- WNK3 | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 140/298 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63615830; called by muse, mutect2, varscan2
- ZBBX | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 119/216 reads (55%) | catalogued as COSV100283542; called by muse, mutect2, varscan2
- ZBTB40 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 195/408 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754749411; called by muse, mutect2, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 241/538 reads (45%) | catalogued as rs781677398, COSV57709922; called by mutect2, varscan2
- ZFAT | c.1427A>G p.H476R | Missense Mutation (SNP) | VAF 300/565 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100914581; called by muse, mutect2, varscan2
- ZFP28 | c.1378G>A p.G460S | Missense Mutation (SNP) | VAF 102/231 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.38); catalogued as rs950434083; called by muse, mutect2, varscan2
- ZFP69 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as rs775673778, COSV65529219; called by muse, mutect2, varscan2
- ZFYVE21 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs746549395, COSV52451018; called by muse, mutect2, varscan2
- ZIK1 | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100277667, COSV56738657; called by muse, mutect2, varscan2
- ZKSCAN4 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 120/286 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs758230777, COSV66023365, COSV66023426; called by muse, mutect2, varscan2
- ZMIZ1 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 165/370 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); catalogued as rs545073892; called by muse, mutect2, varscan2
- ZNF223 | c.1346del p.N449Tfs*21 | Frame Shift Del (DEL) | VAF 80/186 reads (43%) | catalogued as rs758726370; called by mutect2, varscan2
- ZNF256 | c.1126A>G p.T376A | Missense Mutation (SNP) | VAF 141/332 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1372051783; called by muse, mutect2, varscan2
- ZNF329 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 174/344 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs531923322; called by muse, mutect2, varscan2
- ZNF34 | c.664dup p.T222Nfs*6 | Frame Shift Ins (INS) | VAF 70/205 reads (34%) | catalogued as rs751927309; called by mutect2, varscan2
- ZNF469 | c.3185G>A p.R1062H (on ENST00000437464; = p.R1090H on NM_001367624.2) | Missense Mutation (SNP) | VAF 192/383 reads (50%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.746); catalogued as COSV101458783; called by muse, mutect2, varscan2
- ZNF469 | c.9976C>T p.R3326C (on ENST00000437464; = p.R3354C on NM_001367624.2) | Missense Mutation (SNP) | VAF 275/518 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349950723; called by muse, mutect2, varscan2
- ZNF585A | c.1919G>A p.G640E (on ENST00000292841 / NM_001288800.2; = p.G585E on NM_152655.3) | Missense Mutation (SNP) | VAF 228/486 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53065867, COSV99492781; called by muse, mutect2
- ZNF592 | c.2736G>T p.K912N | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV55438689; called by muse, mutect2
- ZNF641 | c.983A>G p.N328S | Missense Mutation (SNP) | VAF 52/385 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1343823056; called by muse, mutect2, varscan2
- ZNF681 | c.99G>T p.M33I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as COSV68073931; called by muse, mutect2, varscan2
- ZNF71 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 252/505 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs763175149, COSV60150140; called by muse, mutect2, varscan2
- ZNF71 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 241/503 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV60146278, COSV60147995; called by muse, mutect2, varscan2
- ZNF714 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 97/190 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs751250571, COSV99395147; called by muse, mutect2, varscan2
- ZNF784 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 291/624 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.921); catalogued as rs913179025, COSV57596750; called by muse, mutect2, varscan2
- ZNF800 | c.275G>A p.C92Y | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56175356; called by muse, mutect2, varscan2
- ZNF98 | c.342del p.K114Nfs*9 | Frame Shift Del (DEL) | VAF 20/208 reads (10%) | catalogued as COSV63335911; called by mutect2, pindel
- ZNRF3 | c.2582C>T p.P861L (on ENST00000544604 / NM_001206998.2; = p.P761L on NM_032173.3) | Missense Mutation (SNP) | VAF 233/467 reads (50%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs1400184077, COSV60439654; called by muse, mutect2, varscan2
- ZSWIM6 | c.3103C>T p.R1035W | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs931029484; called by muse, mutect2
- AARS2 | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by mutect2, varscan2
- ABCA13 | c.5342T>C p.I1781T | Missense Mutation (SNP) | VAF 108/229 reads (47%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ABCB1 | c.3419T>C p.V1140A | Missense Mutation (SNP) | VAF 177/357 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- ABCB5 | c.572C>A p.T191N | Missense Mutation (SNP) | VAF 163/311 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by mutect2, varscan2
- ABCC12 | c.2573G>T p.S858I | Missense Mutation (SNP) | VAF 197/416 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ABCC2 | c.2567C>T p.A856V | Missense Mutation (SNP) | VAF 82/223 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ABHD13 | c.988del p.T330Lfs*5 | Frame Shift Del (DEL) | VAF 68/162 reads (42%) | called by mutect2, pindel, varscan2
- ABI1 | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 107/218 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABL1 | c.31dup p.D11Gfs*36 | Frame Shift Ins (INS) | VAF 115/281 reads (41%) | called by mutect2, pindel, varscan2
- AC025165.3 | c.118A>G p.I40V | Missense Mutation (SNP) | VAF 46/343 reads (13%) | SIFT tolerated, low confidence (0.59); called by muse, mutect2, varscan2
- AC099489.1 | c.8702dup p.P2902Sfs*27 | Frame Shift Ins (INS) | VAF 228/546 reads (42%) | called by mutect2, pindel, varscan2
- AC100868.1 | c.1944dup p.T649Hfs*7 | Frame Shift Ins (INS) | VAF 377/728 reads (52%) | called by mutect2, pindel, varscan2
- ACADVL | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 153/290 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- ACAN | c.5953A>G p.S1985G | Missense Mutation (SNP) | VAF 138/269 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ACP2 | c.1019T>C p.L340P | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- ACSM5 | c.454A>T p.K152* | Nonsense Mutation (SNP) | VAF 109/242 reads (45%) | called by muse, mutect2, varscan2
- ACSS1 | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 139/346 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- ACTR6 | c.942del p.F314Lfs*6 | Frame Shift Del (DEL) | VAF 91/211 reads (43%) | called by mutect2, pindel, varscan2
- ACTR6 | c.1175A>C p.E392A | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- ACVR2A | c.285dup p.D96Rfs*4 | Frame Shift Ins (INS) | VAF 71/173 reads (41%) | called by mutect2, varscan2
- ADAMTS1 | c.888del p.S297Afs*11 | Frame Shift Del (DEL) | VAF 210/426 reads (49%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.2981G>A p.G994D | Missense Mutation (SNP) | VAF 174/372 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY3 | c.730T>C p.Y244H | Missense Mutation (SNP) | VAF 170/379 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.658T>G p.L220V | Missense Mutation (SNP) | VAF 165/302 reads (55%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ADGRG3 | c.535A>G p.N179D | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- ADGRG4 | c.5630C>A p.P1877H | Missense Mutation (SNP) | VAF 201/399 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADH6 | c.25A>G p.R9G | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, varscan2
- ADRA2A | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 260/546 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFF2 | c.1217A>G p.N406S | Missense Mutation (SNP) | VAF 110/254 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AFF2 | c.1887del p.K629Nfs*126 | Frame Shift Del (DEL) | VAF 45/409 reads (11%) | called by mutect2, pindel, varscan2
- AFF4 | c.586A>G p.R196G | Missense Mutation (SNP) | VAF 109/253 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AGAP5 | c.2039G>A p.G680D | Missense Mutation (SNP) | VAF 79/293 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHDC1 | c.613A>G p.R205G | Missense Mutation (SNP) | VAF 157/522 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- AJM1 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 259/588 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- AKAP8 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 182/323 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- AL035460.1 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 258/493 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ANGPTL6 | c.74C>A p.P25Q | Missense Mutation (SNP) | VAF 27/787 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.108); called by muse, mutect2
- ANHX | c.393del p.S132Pfs*7 | Frame Shift Del (DEL) | VAF 129/276 reads (47%) | called by mutect2, pindel, varscan2
- ANKRD65 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 208/446 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- ANKRD66 | c.19A>G p.M7V | Missense Mutation (SNP) | VAF 116/236 reads (49%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD9 | c.103T>C p.F35L | Missense Mutation (SNP) | VAF 40/411 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- AP001781.2 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 200/453 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP3B2 | c.1688T>C p.V563A | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2
- APCDD1L | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 169/340 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AQR | c.3922T>C p.S1308P | Missense Mutation (SNP) | VAF 151/304 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- ARHGAP31 | c.204G>A p.R68= | Splice Region (SNP) | VAF 12/235 reads (5%) | called by muse, mutect2
- ARHGAP39 | c.2170A>G p.S724G | Missense Mutation (SNP) | VAF 59/678 reads (9%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.637); called by muse, mutect2
- ARHGEF1 | c.1030del p.L344Wfs*12 | Frame Shift Del (DEL) | VAF 145/316 reads (46%) | called by mutect2, pindel, varscan2
- ARHGEF25 | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARID1B | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 81/790 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, varscan2
- ARID1B | c.1367dup p.A457Gfs*78 | Frame Shift Ins (INS) | VAF 174/422 reads (41%) | called by mutect2, pindel, varscan2
- ARID2 | c.212A>C p.E71A | Missense Mutation (SNP) | VAF 92/200 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 130/328 reads (40%) | called by mutect2, pindel, varscan2
- ARMC3 | c.165del p.G56Vfs*17 | Frame Shift Del (DEL) | VAF 43/116 reads (37%) | called by mutect2, pindel, varscan2
- ARMH4 | c.1164A>T p.R388S | Missense Mutation (SNP) | VAF 164/319 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ARRDC4 | c.220del p.R74Afs*18 | Frame Shift Del (DEL) | VAF 260/589 reads (44%) | called by mutect2, pindel, varscan2
- ARSA | c.1054A>G p.N352D | Missense Mutation (SNP) | VAF 183/396 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ARSB | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 116/267 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASB13 | c.608A>G p.E203G | Missense Mutation (SNP) | VAF 234/430 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ASH2L | c.1852G>A p.V618M | Missense Mutation (SNP) | VAF 125/262 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASNS | c.896C>A p.A299D | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ASPDH | c.625dup p.V209Gfs*8 (on ENST00000389208 / NM_001114598.2; = p.V104Gfs*8 on NM_001024656.3) | Frame Shift Ins (INS) | VAF 142/379 reads (37%) | called by mutect2, pindel, varscan2
- ASXL1 | c.3980C>T p.A1327V | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- ATIC | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 113/242 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP2B2 | c.2012G>A p.S671N (on ENST00000352432; = p.S637N on NM_001683.5) | Missense Mutation (SNP) | VAF 14/441 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- ATP5PD | c.320_323del p.L107Qfs*6 | Frame Shift Del (DEL) | VAF 113/252 reads (45%) | called by mutect2, pindel, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 385/628 reads (61%) | called by pindel, varscan2
- BACH2 | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 139/277 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BAP1 | c.1328dup p.N443Kfs*8 | Frame Shift Ins (INS) | VAF 97/398 reads (24%) | called by mutect2, pindel, varscan2
- BCAR1 | c.1244del p.P415Qfs*56 | Frame Shift Del (DEL) | VAF 216/458 reads (47%) | called by mutect2, varscan2
- BCL2A1 | c.430T>C p.F144L | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BCL9 | c.1934del p.P645Qfs*14 | Frame Shift Del (DEL) | VAF 152/373 reads (41%) | called by mutect2, pindel, varscan2
- BCORL1 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 313/636 reads (49%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BEGAIN | c.334A>G p.R112G | Missense Mutation (SNP) | VAF 19/530 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2
- BIRC6 | c.13201G>A p.A4401T | Missense Mutation (SNP) | VAF 142/274 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- BNC2 | c.1604G>A p.G535D | Missense Mutation (SNP) | VAF 172/366 reads (47%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- BOD1L1 | c.8048del p.N2683Mfs*19 | Frame Shift Del (DEL) | VAF 101/276 reads (37%) | called by pindel, varscan2
- BOD1L1 | c.1707del p.V570* | Frame Shift Del (DEL) | VAF 46/184 reads (25%) | called by mutect2, varscan2
- BRF2 | c.1039dup p.Q347Pfs*36 | Frame Shift Ins (INS) | VAF 167/423 reads (39%) | called by mutect2, pindel, varscan2
- BTNL9 | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 196/400 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C12orf50 | c.71G>T p.S24I | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- C18orf63 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- C19orf57 | c.1285A>G p.M429V | Missense Mutation (SNP) | VAF 243/498 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C19orf81 | c.545T>C p.V182A | Missense Mutation (SNP) | VAF 230/458 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C2CD4C | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 149/754 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C3orf33 | c.836T>C p.L279P (on ENST00000340171 / NM_001308229.2; = p.L236P on NM_173657.2) | Missense Mutation (SNP) | VAF 93/179 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- C4orf50 | c.654dup p.A219Rfs*19 (on ENST00000324058; = p.A1451Rfs*19 on NM_001364689.1 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 132/337 reads (39%) | called by mutect2, pindel, varscan2
- C4orf54 | c.2783C>T p.A928V | Missense Mutation (SNP) | VAF 149/327 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- C6orf15 | c.568del p.I190Sfs*23 | Frame Shift Del (DEL) | VAF 278/707 reads (39%) | called by mutect2, pindel, varscan2
- CACNA1B | c.2762G>A p.R921H | Missense Mutation (SNP) | VAF 23/382 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- CACNA1D | c.4234A>G p.M1412V (on ENST00000350061 / NM_001128840.3; = p.M1432V on NM_000720.4) | Missense Mutation (SNP) | VAF 121/249 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CACNA1E | c.2532G>C p.K844N | Missense Mutation (SNP) | VAF 177/397 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CADM3 | c.403A>G p.I135V (on ENST00000368125 / NM_001127173.3; = p.I169V on NM_021189.5) | Missense Mutation (SNP) | VAF 109/234 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CADPS2 | c.2402A>G p.K801R | Missense Mutation (SNP) | VAF 112/219 reads (51%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- CAMTA1 | c.4139G>T p.S1380I | Missense Mutation (SNP) | VAF 110/242 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.102); called by mutect2, varscan2
- CAPRIN1 | c.20A>G p.H7R | Missense Mutation (SNP) | VAF 214/421 reads (51%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CARD10 | c.1628dup p.K544* | Frame Shift Ins (INS) | VAF 127/312 reads (41%) | called by mutect2, pindel, varscan2
- CARD6 | c.1625A>G p.Q542R | Missense Mutation (SNP) | VAF 139/284 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- CATSPERD | c.2248G>T p.A750S | Missense Mutation (SNP) | VAF 256/536 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2
- CCDC112 | c.706del p.R236Gfs*7 | Frame Shift Del (DEL) | VAF 19/191 reads (10%) | called by mutect2, pindel, varscan2
- CCDC134 | c.662G>T p.R221M | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC136 | c.977A>C p.E326A | Missense Mutation (SNP) | VAF 116/237 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC14 | c.1364G>A p.R455K (on ENST00000488653; = p.R407K on NM_022757.5) | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- CCDC168 | c.17437dup p.I5813Nfs*29 | Frame Shift Ins (INS) | VAF 111/272 reads (41%) | called by mutect2, varscan2
- CCDC39 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 124/287 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CCDC91 | c.110-1G>C p.X37_splice | Splice Site (SNP) | VAF 83/157 reads (53%) | called by muse, mutect2, varscan2
- CCNB3 | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 164/383 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by mutect2, varscan2
- CCNB3 | c.1731G>T p.E577D | Missense Mutation (SNP) | VAF 172/345 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCNK | c.1605_1607del p.P536del | In Frame Del (DEL) | VAF 66/155 reads (43%) | called by pindel, varscan2
- CCNQ | c.422C>A p.P141Q | Missense Mutation (SNP) | VAF 102/177 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCT6B | c.1506del p.K502Nfs*9 | Frame Shift Del (DEL) | VAF 88/234 reads (38%) | called by mutect2, pindel, varscan2
- CCT7 | c.470del p.K157Sfs*4 | Frame Shift Del (DEL) | VAF 71/282 reads (25%) | called by mutect2, pindel, varscan2
- CDAN1 | c.3515_3516del p.I1172Rfs*18 | Frame Shift Del (DEL) | VAF 146/368 reads (40%) | called by mutect2, pindel, varscan2
- CDC42BPB | c.4958_4959del p.V1653Afs*7 | Frame Shift Del (DEL) | VAF 126/389 reads (32%) | called by pindel, varscan2
- CDK12 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 123/255 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CDK12 | c.3844G>T p.V1282F (on ENST00000447079 / NM_016507.4; = p.V1273F on NM_015083.3) | Missense Mutation (SNP) | VAF 108/256 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, varscan2
- CDKN2AIP | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 132/275 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- CDX2 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 268/528 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDYL2 | c.1063G>T p.G355W | Missense Mutation (SNP) | VAF 56/388 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR3 | c.1392del p.N465Tfs*69 | Frame Shift Del (DEL) | VAF 248/617 reads (40%) | called by mutect2, pindel, varscan2
- CEP120 | c.2616del p.K872Nfs*9 | Frame Shift Del (DEL) | VAF 110/305 reads (36%) | called by mutect2, pindel, varscan2
- CEP120 | c.1366T>C p.F456L | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CEP250 | c.3874A>G p.R1292G | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CEP44 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CERS1 | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 107/227 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- CFAP100 | c.125del p.N42Tfs*48 | Frame Shift Del (DEL) | VAF 92/231 reads (40%) | called by mutect2, pindel, varscan2
- CFAP44 | c.2160del p.E721Nfs*100 | Frame Shift Del (DEL) | VAF 166/438 reads (38%) | called by mutect2, pindel, varscan2
- CFAP47 | c.6320dup p.I2108Dfs*41 | Frame Shift Ins (INS) | VAF 84/207 reads (41%) | called by mutect2, pindel, varscan2
- CFAP65 | c.2584del p.Q862Sfs*6 | Frame Shift Del (DEL) | VAF 110/256 reads (43%) | called by mutect2, pindel, varscan2
- CFAP69 | c.123T>C p.D41= | Splice Region (SNP) | VAF 84/166 reads (51%) | called by muse, varscan2
- CFDP1 | c.848A>G p.H283R | Missense Mutation (SNP) | VAF 130/244 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, varscan2
- CFTR | c.3130G>T p.E1044* | Nonsense Mutation (SNP) | VAF 91/189 reads (48%) | called by muse, mutect2, varscan2
- CGB5 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 92/457 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- CHD8 | c.2848G>A p.A950T (on ENST00000646647 / NM_001170629.2; = p.A671T on NM_020920.4) | Missense Mutation (SNP) | VAF 150/328 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHGA | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 181/350 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CHRNA10 | c.962A>G p.N321S | Missense Mutation (SNP) | VAF 174/391 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- CILP2 | c.1728A>T p.E576D | Missense Mutation (SNP) | VAF 252/482 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLASRP | c.284del p.P95Lfs*81 | Frame Shift Del (DEL) | VAF 150/432 reads (35%) | called by pindel, varscan2
- CLEC4F | c.248A>G p.H83R | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CLIC5 | c.649del p.A217Hfs*40 | Frame Shift Del (DEL) | VAF 114/286 reads (40%) | called by mutect2, pindel, varscan2
- CLTC | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.996); called by muse, varscan2
- CNIH1 | c.394del p.Y132Tfs*6 | Frame Shift Del (DEL) | VAF 75/173 reads (43%) | called by mutect2, pindel, varscan2
- CNOT6 | c.1056del p.K352Nfs*20 | Frame Shift Del (DEL) | VAF 90/214 reads (42%) | called by mutect2, pindel, varscan2
- CNTNAP1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 211/436 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNTNAP5 | c.891G>T p.E297D | Missense Mutation (SNP) | VAF 132/242 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COL18A1 | c.3102dup p.P1035Afs*10 (on ENST00000359759 / NM_130444.3; = p.P800Afs*10 on NM_030582.4) | Frame Shift Ins (INS) | VAF 109/318 reads (34%) | called by mutect2, pindel, varscan2
- COL6A6 | c.2738A>G p.Q913R | Missense Mutation (SNP) | VAF 211/400 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); called by muse, mutect2
- COP1 | c.497A>T p.D166V | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); called by muse, varscan2
- CPA6 | c.1238T>C p.L413P | Missense Mutation (SNP) | VAF 28/337 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); called by muse, mutect2
- CPAMD8 | c.4855G>A p.A1619T (on ENST00000651564; = p.A1572T on NM_015692.5) | Missense Mutation (SNP) | VAF 134/276 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CPD | c.690dup p.A231Rfs*38 | Frame Shift Ins (INS) | VAF 168/428 reads (39%) | called by mutect2, pindel, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 136/296 reads (46%) | called by mutect2, varscan2
- CRACD | c.501dup p.Q168Tfs*17 | Frame Shift Ins (INS) | VAF 100/248 reads (40%) | called by mutect2, varscan2
- CRYBG2 | c.3398C>A p.P1133H | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CRYZ | c.821C>A p.S274* | Nonsense Mutation (SNP) | VAF 58/132 reads (44%) | called by muse, mutect2, varscan2
- CSDE1 | c.833del p.N278Tfs*15 (on ENST00000358528 / NM_001007553.3; = p.N247Tfs*15 on NM_007158.6) | Frame Shift Del (DEL) | VAF 70/165 reads (42%) | called by mutect2, pindel, varscan2
- CSKMT | c.662A>C p.Q221P | Missense Mutation (SNP) | VAF 149/320 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CSMD2 | c.4588A>G p.S1530G | Missense Mutation (SNP) | VAF 109/465 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- CSNK2A1 | c.694T>A p.F232I | Missense Mutation (SNP) | VAF 33/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CT47B1 | c.494A>G p.N165S | Missense Mutation (SNP) | VAF 194/384 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CTBP2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 129/243 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CTBS | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- CTNNA3 | c.1059del p.E354Kfs*6 | Frame Shift Del (DEL) | VAF 46/182 reads (25%) | called by pindel, varscan2
- CTNNA3 | c.1048-12_1053delinsCTTCTTTGCAGGCTGG p.X350_splice | Splice Site (DEL) | VAF 64/256 reads (25%) | called by pindel, varscan2*
- CUL4B | c.584dup p.K196Efs*8 | Frame Shift Ins (INS) | VAF 31/302 reads (10%) | called by mutect2, pindel, varscan2
- CUX1 | c.4090dup p.E1364Gfs*187 | Frame Shift Ins (INS) | VAF 250/643 reads (39%) | called by mutect2, pindel, varscan2
- CYFIP2 | c.3574C>A p.L1192M (on ENST00000616178 / NM_001291722.2; = p.L1167M on NM_014376.4) | Missense Mutation (SNP) | VAF 122/251 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CYP3A7 | c.241A>G p.M81V | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP4A11 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 102/205 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- DAB2IP | c.1817G>A p.G606D (on ENST00000408936; = p.G578D on NM_032552.3) | Missense Mutation (SNP) | VAF 41/430 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCC | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- DDIT4L | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 173/355 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX24 | c.2411G>A p.S804N | Missense Mutation (SNP) | VAF 254/518 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX60 | c.4010T>C p.V1337A | Missense Mutation (SNP) | VAF 131/258 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- DEAF1 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 197/402 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DGAT2L6 | c.766dup p.I256Nfs*42 | Frame Shift Ins (INS) | VAF 196/407 reads (48%) | called by mutect2, varscan2
- DIDO1 | c.5332G>A p.A1778T | Missense Mutation (SNP) | VAF 173/418 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DISC1 | c.1787T>C p.I596T | Missense Mutation (SNP) | VAF 86/173 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- DLG5 | c.362T>C p.L121P | Missense Mutation (SNP) | VAF 154/324 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH1 | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 88/175 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH14 | c.6553T>G p.L2185V (on ENST00000445597; = p.L2838V on NM_001367479.1) | Missense Mutation (SNP) | VAF 96/197 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DNAH5 | c.2596G>A p.A866T | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- DNAH9 | c.12331G>T p.E4111* | Nonsense Mutation (SNP) | VAF 117/254 reads (46%) | called by muse, mutect2, varscan2
- DNAJC9 | c.567G>T p.R189S | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- DNMT1 | c.4815A>G p.S1605= | Splice Region (SNP) | VAF 58/246 reads (24%) | called by muse, varscan2
- DNPEP | c.767A>G p.Q256R | Missense Mutation (SNP) | VAF 104/230 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- DNPH1 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 173/354 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- DPF1 | c.938T>G p.L313R | Missense Mutation (SNP) | VAF 197/371 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- DPP3 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 242/479 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DYNC2H1 | c.5488C>A p.L1830I | Missense Mutation (SNP) | VAF 95/190 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- ECT2 | c.1300A>G p.K434E (on ENST00000392692 / NM_001349098.2; = p.K403E on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT tolerated (0.93); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- EDRF1 | c.1582A>C p.N528H (on ENST00000356792 / NM_001202438.2; = p.N494H on NM_015608.2) | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- EEF1G | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- EGFLAM | c.647T>A p.V216E | Missense Mutation (SNP) | VAF 166/346 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- EHD4 | c.62T>G p.V21G | Missense Mutation (SNP) | VAF 74/622 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- EIF2AK4 | c.2462A>G p.D821G | Missense Mutation (SNP) | VAF 164/314 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EIF4A1 | c.611A>T p.N204I | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- EIF5A | c.428_429del p.E143Gfs*53 | Frame Shift Del (DEL) | VAF 45/345 reads (13%) | called by pindel, varscan2
- ELP5 | c.836+2_836+5del p.X279_splice | Splice Site (DEL) | VAF 66/159 reads (42%) | called by mutect2, pindel, varscan2
- EMSY | c.1504A>G p.T502A | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENOX1 | c.1229G>A p.S410N | Missense Mutation (SNP) | VAF 100/232 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPM2A | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 158/317 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
889 further variants in this file (464 protein-altering or splice-affecting, 350 silent, 75 other) are not listed here.
